CCDI case PBBWER — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/42523658-625d-4832-9360-493a334859b0

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,232 days).

Biospecimens (3 samples)
- Sample 0DJHDW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHEC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJHH3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
